Surgical pathology report (de-identified scan), TCGA case TCGA-NP-A5GZ, project TCGA-KICH (Kidney Chromophobe), tissue source site International Genomics Consortium, specimen TCGA-NP-A5GZ-01A (Primary Tumor).

[page 1 of 3]
Referring Physician:

Gender: F

Ref#: Hosp#: Patient Location:

Date of Service: Date Received: Inpatient

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

KIDNEY, RIGHT, NEPHRECTOMY:

- Chromophobe renal cell carcinoma.
- Tumor size: 9.5 cm.
- Surgical margins free of tumor.

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade: Chromophobe renal cell carcinoma, Grade 2.

Primary tumor: pT2a.

Regional lymph nodes: pNX.

Distant metastasis: pMX.

Pathologic stage: II.

Lymphovascular invasion: Not identified.

Margin status: R0, negative.

ICD-6-3

Carcinoma, renal cell

Chromophobe type

8317/3

Site: (R) Kidney, NOS

C64.9

Q62 12/20/12

[page 2 of 3]
Patient: [REDACTED]

Case #: [REDACTED]

FINAL SURGICAL PATHOLOGY REPORT

Kidney Tumor Staging Information

(data derived from current specimen, staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol)

Procedure:	Radical nephrectomy.
Specimen type:	Right kidney.
Specimen laterality:	Right.
Tumor Features:	
Tumor size:	9.5 cm.
Tumor focality:	Single focus.
Histologic type:	Chromophobe renal cell carcinoma.
Histologic grade (Fuhrman nuclear grade):	Grade 2.
Sarcomatoid features:	Not identified.
Macroscopic extent of tumor:	Limited to kidney.
Microscopic tumor extension:	Limited to kidney.
Lymph Nodes:	N/A.
Margin Evaluation:	
Distance to closest margin:	Greater than 1 cm from all margins.
Other margins:	N/A.
Pathologic tumor staging descriptors:	
Primary tumor (pT):	pT2a.
Regional Lymph nodes (pN):	pNX.
Distant metastasis (pM):	pMX.
Margin status (R):	R0, negative.
Pathologic stage:	II.
Pathologic findings in non-neoplastic kidney:	Unremarkable.
Additional pathologic findings:	N/A.
Comment:	N/A.

Case #: [REDACTED]

[page 3 of 3]
Patient: [REDACTED]

Case #: [REDACTED]

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

Right Kidney nephrectomy

Clinical History/Operative Dx:

Renal mass

Gross Description:

The specimen is labeled right kidney and is received in formalin. It consists of a nephrectomy specimen which together with perinephric fat weighs 478 grams. The specimen measures 14 cm from superior to inferior, 9 cm from medial to lateral, and 7 cm from anterior to posterior. There is no adrenal gland. The adipose tissue at the upper pole of the kidney has been stripped and disrupted. Along the anterior surface of the kidney is a filmy portion of pale tan tissue suggestive of Gerota's fascia measuring 8 x 4.5 cm. The kidney is prominent bulging along the posterior and lateral surface. At the hilum, the renal artery and renal vein are identified. The vessels are opened and there is no grossly obvious intraluminal tumor. Extending from the hilum is a 6 cm segment of ureter which is 0.4 cm in diameter. The ureter is opened and the urothelium is tan and smooth. There are some slight granularities in the renal pelvis. The renal pelvis is pushed anteriorly due to the bulging tumor. The kidney is bivalved to reveal a somewhat friable, yellow to focally brown tumor which is thinly encapsulated and does not appear to invade the perinephric fat. It measures 9.5 x 7.5 x 6.5 cm. It abuts the renal pelvis but does not appear to invade the calyces or renal pelvis. Representative sections of the tumor are submitted for research purposes. Away from the tumor, the corticomedullary junction of the kidney appears distinct and cortical thickness is 0.6 cm. No other masses are identified. There are no lymph nodes identified in the peripelvic fat. Representative sections are submitted. Section summary: A1) surgical margin, renal artery, renal vein and ureter, A2) additional sections of ureter and ureteropelvic junction, A3) Gerota's fascia, A4-A7) representative tumor, A8) section of tumor at renal pelvis, A9) uninvolved kidney. [REDACTED]

Microscopic Description:

Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Immunohistochemistry was performed with adequate control for Vimentin, pancytokeratin, CK7, E-Cadherin, PAX-8, and CD10. Sections show a tumor composed of solid proliferation of cells with thickwalled blood vessels and enlarged perivascular cells. The cells are polygonal with transparent to slightly eosinophilic cytoplasm and prominent cell membranes. The nuclei are irregular and focally wrinkled with small nucleoli. Perinuclear halos are seen. The tumor cells are positive for CK7, E-cadherin, PAX-8 and pancytokeratin (patchy, focal) and are negative for vimentin and CD10. Taken together, the histomorphology and immunohistochemistry staining pattern are consistent with chromophobe renal cell carcinoma.

An intradepartmental consultation with [REDACTED] was obtained.

Case #: [REDACTED]

Source: NCI Genomic Data Commons file 772fcef0-f21f-4b06-b36a-35dd70b5e34e (TCGA-NP-A5GZ.76D9E899-52EE-4383-97F5-BF6478D1D508.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).